Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3ML, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3ML-06A (Metastatic).

1CD-0-3
Melanoma, NOS 8720/3
Site: lymph node, submental c77.0
lw 1/7/12

DIAGNOSIS

Patient ID - Sample ID

(A) SUBMENTAL LYMPH NODES:

METASTATIC MALIGNANT MELANOMA IN THREE OF THREE LYMPH NODES (3/3).
LARGEST TUMOR SIZE IS 17.0 MM (AS MEASURED ON THE SLIDE).
EXTRACAPSULAR EXTENSION IS PRESENT.

MULTIFOCAL METASTATIC MALIGNANT MELANOMA IN SOFT TISSUE.
(Entirely replaced lymph nodes cannot be ruled out.)

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) SUBMENTAL LYMPH NODES - An irregular fragment of fibroadipose tissue measuring 5.0 x 3.0 x 1.0 cm. The specimen is serially sectioned and six lymph nodes are identified ranging in size from 0.3 x 0.2 x 0.2 cm to 2.0 x 1.0 x 1.0 cm.

SECTION CODE: A1, A2, largest possible lymph node; A3, two possible lymph nodes; A4, one possible lymph node bisected; A5, two possible lymph nodes.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

lw 1/7/12

Source: NCI Genomic Data Commons file dd766b93-9411-43be-8c95-bf75bac59c97 (TCGA-D3-A3ML.80F131FA-7E24-4210-800F-3E6F442CAB6F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).